Somatic mutation profile of tumor specimen TCGA-HU-A4GC-01A (aliquot TCGA-HU-A4GC-01A-12D-A25D-08) from TCGA case TCGA-HU-A4GC, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.7 years (27,267 days).
Specimen TCGA-HU-A4GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9eac2ff-85f3-4b4f-864a-313e8cfc9a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GC-10A (Blood Derived Normal), aliquot TCGA-HU-A4GC-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79dedb5a-0874-408c-ae82-88a1bd795c75

The open-access MAF lists 152 somatic variants for this specimen: 112 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 38, Nonsense Mutation 10, Splice Site 3, Splice Region 2, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2del p.X307_splice | Splice Site (DEL) | VAF 18/73 reads (25%) | hotspot (GDC flag); catalogued as COSV52693974, COSV52706655, COSV52945558, COSV53066011; called by mutect2, pindel, varscan2
- TTN | c.86190G>A p.W28730* (on ENST00000591111; = p.W21306* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | catalogued as rs1553538469, COSV59901996; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4553C>T p.T1518I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV54437270; called by muse, mutect2, varscan2
- AQP8 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139054676; called by muse, mutect2, varscan2
- ARAP1 | c.4071C>T p.C1357= (on ENST00000393609 / NM_001040118.2; = p.C1112= on NM_015242.4) | Splice Region (SNP) | VAF 77/226 reads (34%) | catalogued as COSV61989529; called by muse, mutect2, varscan2
- ARHGAP20 | c.2143C>A p.L715I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs764104874, COSV52807074; called by muse, mutect2, varscan2
- ARMC3 | c.1827C>T p.Y609= | Splice Region (SNP) | VAF 11/74 reads (15%) | catalogued as rs371745700, COSV53057401; called by muse, mutect2, varscan2
- ATP10B | c.3958C>T p.Q1320* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV59144330; called by muse, mutect2, varscan2
- BARHL1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs376566705; called by muse, mutect2, varscan2
- BBX | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57879470; called by muse, mutect2, varscan2
- CACNA1C | c.1653G>T p.W551C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59698494; called by muse, mutect2
- CCDC86 | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as COSV57124530; called by muse, mutect2, varscan2
- CCT7 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV57821370; called by muse, mutect2, varscan2
- CDH12 | c.1496A>G p.E499G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66389389; called by muse, mutect2, varscan2
- CHCHD2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs778377000, COSV68169837; called by muse, mutect2, varscan2
- CHD4 | c.4589C>T p.P1530L (on ENST00000357008 / NM_001363606.2; = p.P1543L on NM_001273.5) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs1016423925, COSV58895415; called by muse, mutect2
- CHRD | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs199856196, COSV52605712; called by muse, mutect2, varscan2
- CHRM2 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as rs1462512567, COSV57766078; called by muse, mutect2, varscan2
- CHRNA4 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs762374374, COSV64718527; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLYBL | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV59217406; called by muse, mutect2, varscan2
- CNTNAP5 | c.2495T>G p.L832R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV70474139, COSV99081553; called by muse, mutect2, varscan2
- COL22A1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV57324808; called by muse, mutect2, varscan2
- CTSW | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV57171752; called by muse, mutect2, varscan2
- CXXC1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV53273321; called by muse, mutect2, varscan2
- DAGLA | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV57194287; called by muse, mutect2, varscan2
- DDX42 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV63789385; called by muse, mutect2, varscan2
- DHODH | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV54661261; called by muse, mutect2, varscan2
- DNAH5 | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946204829, COSV54202034; called by muse, mutect2, varscan2
- DNM2 | c.1864C>T p.R622* (on ENST00000355667 / NM_001005360.3; = p.R618* on NM_004945.3) | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs1439919754, COSV58957366; called by muse, mutect2, varscan2
- DST | c.7032A>T p.E2344D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV99752093; called by muse, mutect2, varscan2
- DYNC1H1 | c.4232G>A p.R1411H | Missense Mutation (SNP) | VAF 161/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64134606; called by muse, mutect2, varscan2
- ECHDC1 | c.333C>G p.F111L (on ENST00000531967 / NM_001139510.1; = p.F105L on NM_018479.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58931428; called by muse, mutect2, varscan2
- EIF2AK1 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52236335; called by muse, mutect2, varscan2
- EPHA5 | c.1426A>G p.K476E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV56632497, COSV99898374; called by muse, mutect2
- ESPNL | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs572001508, COSV58032451; called by muse, mutect2, varscan2
- FASTK | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV52538990, COSV99879580; called by muse, mutect2, varscan2
- FAT4 | c.7054G>A p.V2352I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs147151922; called by muse, mutect2, varscan2
- FOXRED2 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.14); catalogued as rs780157982, COSV53398951; called by muse, mutect2, varscan2
- FREM2 | c.6742+1G>C p.X2248_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54829554; called by muse, mutect2, varscan2
- GALE | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528467258, CM054731, COSV52525176; called by muse, mutect2, varscan2
- GLI3 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1419861206, COSV67885531; called by muse, mutect2, varscan2
- GNB1L | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV61547810; called by muse, mutect2, varscan2
- GPR20 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373939324; called by muse, mutect2
- GRM8 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs913988684, COSV58804599, COSV58817034; called by muse, mutect2, varscan2
- HERC1 | c.3451C>T p.R1151W | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs771392135, COSV71246030; called by muse, mutect2, varscan2
- HRNR | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs552018177, COSV64254655; called by muse, mutect2
- IGSF10 | c.3295T>C p.S1099P | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56781980; called by muse, mutect2, varscan2
- IRF8 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs370022572, COSV51896544; called by muse, mutect2, varscan2
- KCNJ2 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV54659949; called by muse, mutect2, varscan2
- KIAA1210 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs369057021, COSV68175642; called by muse, mutect2, varscan2
- L3MBTL1 | c.2114A>G p.H705R (on ENST00000418998 / NM_001377303.1; = p.H615R on NM_015478.7) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV64227919; called by muse, mutect2, varscan2
- LRP1B | c.5093T>G p.L1698R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67189309; called by muse, mutect2, varscan2
- MARF1 | c.2612C>A p.A871D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); catalogued as COSV60020124; called by muse, mutect2, varscan2
- METTL17 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1229930537, COSV53868818; called by muse, mutect2, varscan2
- MICAL3 | c.4650G>A p.W1550* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV71588056; called by muse, mutect2, varscan2
- MRTFA | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780892147, COSV62931415; called by muse, mutect2, varscan2
- MS4A14 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs146613208; called by muse, mutect2, varscan2
- MTUS2 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs548916506, COSV70913971; called by muse, mutect2, varscan2
- MUC4 | c.15538C>T p.L5180F (on ENST00000463781 / NM_018406.7; = p.L944F on NM_004532.6) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57767499; called by muse, mutect2
- MYO5A | c.4384C>T p.R1462* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV62556947; called by muse, mutect2, varscan2
- NBEA | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 21/156 reads (13%) | catalogued as rs1288199769, COSV59762270; called by muse, mutect2, varscan2
- NELL2 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV61569633, COSV61580248; called by muse, mutect2, varscan2
- NKAPL | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs1046209467, COSV59197035; called by muse, mutect2, varscan2
- NOMO3 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs201534093, COSV99530693; called by muse, mutect2, varscan2
- OR51F1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs776481103, COSV58578915; called by muse, mutect2, varscan2
- P2RY1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1298828960, COSV59308801; called by muse, mutect2, varscan2
- PAK6 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778815914, COSV53044455, COSV99544253; called by muse, mutect2, varscan2
- PATZ1 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53228751; called by muse, mutect2, varscan2
- PCDHB16 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53357508; called by muse, mutect2, varscan2
- PCDHGA12 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52744421; called by muse, mutect2, varscan2
- PDCD11 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV58915283; called by muse, mutect2
- PDE2A | c.2434C>A p.Q812K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57802766; called by muse, mutect2, varscan2
- PHKB | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV54515049; called by muse, mutect2
- PLEKHS1 | c.199A>G p.I67V (on ENST00000369310 / NM_182601.1; = p.I73V on NM_024889.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.121); catalogued as COSV63054158; called by muse, mutect2, varscan2
- PRAMEF2 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV53572623; called by muse, mutect2, varscan2
- PRKDC | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1291229034, COSV58043949; called by muse, mutect2, varscan2
- PTCHD3 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV71256319; called by muse, mutect2, varscan2
- PXDNL | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100684090, COSV62479258; called by muse, mutect2, varscan2
- RIF1 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV54612754; called by muse, mutect2, varscan2
- ROR2 | c.995A>T p.K332M | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV65216723; called by muse, mutect2, varscan2
- RPE65 | c.597T>A p.N199K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs141527042, COSV52014131; called by mutect2, varscan2
- RYR3 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs371008189, COSV99066346; called by muse, mutect2, varscan2
- SACS | c.12893T>G p.L4298R | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.347); catalogued as COSV66534985; called by muse, mutect2, varscan2
- SAMD15 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53625351; called by muse, mutect2, varscan2
- SAR1A | c.480+1G>A p.X160_splice | Splice Site (SNP) | VAF 30/167 reads (18%) | catalogued as COSV64697771; called by muse, mutect2, varscan2
- SBF1 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs762534000, COSV62365901; called by muse, mutect2, varscan2
- SDCBP2 | c.473G>A p.R158H (on ENST00000339987 / NM_001199784.1; = p.R73H on NM_015685.5) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs747790242, COSV60588347; called by muse, mutect2, varscan2
- SEMA4F | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60281997; called by muse, mutect2, varscan2
- SIGLEC5 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs754092511, COSV55777655, COSV55778007; called by mutect2, varscan2
- SLC12A5 | c.919T>G p.F307V (on ENST00000454036 / NM_001134771.2; = p.F284V on NM_020708.5) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV54789007; called by muse, mutect2, varscan2
- SOX7 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769083723, COSV58730287; called by muse, mutect2, varscan2
- SPRR1A | c.150C>G p.H50Q | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs143282605; called by muse, mutect2, varscan2
- SPTA1 | c.6632G>A p.R2211H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs751062593, COSV63749330; called by muse, mutect2, varscan2
- SRGAP3 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768436049, COSV64530736; called by muse, mutect2, varscan2
- SSTR2 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs779626588, COSV59534882; called by muse, mutect2, varscan2
- STXBP5L | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs865873766, COSV56501319; called by muse, mutect2
- SULF1 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52674011, COSV52677156; called by muse, mutect2, varscan2
- SYNE1 | c.16924A>C p.K5642Q (on ENST00000367255 / NM_182961.4; = p.K5571Q on NM_033071.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV54913992, COSV55115764, COSV99576449; called by muse, mutect2, varscan2
- TCF3 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781162855, COSV53645878; called by muse, mutect2, varscan2
- TRAK2 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60270425; called by muse, mutect2, varscan2
- TTC13 | c.2344A>G p.M782V | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV64167798; called by muse, mutect2
- UBN2 | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56028008, COSV99944335; called by muse, mutect2
- USB1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1226771318, COSV54621096; called by muse, mutect2, varscan2
- WASHC5 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.066); catalogued as rs1382647480, COSV59194264; called by mutect2, varscan2
- ZC3H7B | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1473101966, COSV60960596; called by muse, mutect2, varscan2
- ZCCHC3 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV66642898; called by muse, mutect2
- ZFP69B | c.1402G>C p.V468L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as COSV64315029; called by muse, mutect2, varscan2
- ZNF99 | c.1231A>C p.K411Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.104); catalogued as COSV101233728, COSV68056248; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2471C>A p.P824H | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC6 | c.6496_6505del p.V2166Pfs*7 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- REV3L | c.6195dup p.T2066Yfs*6 | Frame Shift Ins (INS) | VAF 20/127 reads (16%) | called by mutect2, pindel, varscan2
- TTC14 | c.2308_*11del | Nonstop Mutation (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- ABCA12 | c.4968C>T p.T1656= (on ENST00000272895 / NM_173076.3; = p.T1338= on NM_015657.3) | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs138215759; called by muse, mutect2, varscan2
- ACOX3 | c.897G>A p.A299= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs200566318, COSV62710852; called by muse, mutect2, varscan2
- ADGRG4 | c.4239T>G p.T1413= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV54950192; called by muse, mutect2, varscan2
- C9orf116 | c.321C>T p.I107= (on ENST00000429260 / NM_001048265.2; = p.S92L on NM_144654.3) | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs150939171; called by muse, mutect2, varscan2
- CABP2 | c.507C>T p.D169= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs768914726, COSV53708323, COSV53709785; called by muse, mutect2, varscan2
- CACNG3 | c.492C>T p.P164= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs531052899, COSV50064239; called by muse, mutect2, varscan2
- CD1A | c.894T>C p.S298= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as COSV56860365; called by muse, mutect2, varscan2
- CEP192 | c.3972T>A p.G1324= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV58060264; called by muse, mutect2, varscan2
- CFAP251 | c.2499G>A p.T833= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs559061329, COSV56608149; called by muse, mutect2, varscan2
- DDB1 | c.636C>T p.V212= | Silent (SNP) | VAF 35/252 reads (14%) | catalogued as rs754810752, COSV57101199; called by muse, mutect2, varscan2
- DPEP1 | c.63C>T p.D21= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs371346042; called by muse, mutect2
- DSCAM | c.1338G>A p.P446= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs868420288, COSV68020878; called by muse, mutect2, varscan2
- EPHA5 | c.1119C>A p.V373= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1273243130, COSV99896816; called by muse, mutect2, varscan2
- HOXA9 | c.513C>T p.S171= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV58655814; called by muse, mutect2, varscan2
- IPO13 | c.1854C>A p.I618= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100961002, COSV64893839; called by muse, mutect2, varscan2
- MS4A10 | c.228C>A p.G76= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as COSV57632129; called by muse, mutect2, varscan2
- MUC16 | c.14574A>G p.T4858= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV67447023, COSV67468907; called by muse, mutect2, varscan2
- MUC5B | c.14049G>A p.T4683= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs760789184, COSV101500070; called by mutect2, varscan2
- NLRP2 | c.1365G>A p.A455= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs201883695, COSV54752623; called by muse, mutect2, varscan2
- NRXN1 | c.480G>A p.P160= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs771181102, COSV68003367; called by muse, mutect2, varscan2
- OR5K1 | c.669T>C p.L223= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1214069003, COSV60303570; called by muse, mutect2, varscan2
- PAX9 | c.393C>A p.I131= | Silent (SNP) | VAF 74/672 reads (11%) | catalogued as rs772970706, COSV64061206; called by muse, mutect2, varscan2
- PCDH10 | c.243C>T p.R81= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs538631045, COSV52088002; called by muse, mutect2, varscan2
- PCDHA8 | c.1374C>T p.P458= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV65334968; called by muse, mutect2, varscan2
- PCYOX1 | c.276C>T p.I92= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as rs1172079693, COSV52475587; called by muse, mutect2, varscan2
- PREX2 | c.30C>T p.R10= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV55752383; called by muse, mutect2, varscan2
- RARG | c.99C>T p.L33= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100553304; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RNF216 | c.1155C>T p.L385= (on ENST00000425013 / NM_207116.3; = p.L442= on NM_207111.4) | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as rs1417384107, COSV66289357; called by muse, mutect2, varscan2
- SKOR1 | c.495G>A p.S165= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV58243664; called by muse, mutect2, varscan2
- SLC12A5 | c.675C>A p.I225= (on ENST00000454036 / NM_001134771.2; = p.I202= on NM_020708.5) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV54788990; called by muse, mutect2, varscan2
- TBC1D31 | c.393G>A p.S131= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as rs146436284, COSV54869467; called by muse, mutect2, varscan2
- TRPM2 | c.1569C>T p.Y523= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs747647717, COSV55966326; called by muse, mutect2, varscan2
- TTN | c.62394C>T p.P20798= (on ENST00000591111; = p.P13374= on NM_003319.4) | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs747645787, COSV59902017; called by muse, mutect2, varscan2
- UBL4A | c.399C>T p.D133= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs781933473, COSV54835618; called by muse, mutect2, varscan2
- ZNF423 | c.3327C>T p.N1109= (on ENST00000563137 / NM_001379286.1; = p.N1101= on NM_015069.4) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs200411543, COSV52177741; called by muse, mutect2, varscan2
- ZNF578 | c.1140T>C p.F380= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV69735973; called by muse, mutect2, varscan2
- ZNF831 | c.531C>T p.C177= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as rs760365017, COSV64037675; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7745A>G | Intron (SNP) | VAF 8/53 reads (15%) | catalogued as COSV63388021; called by muse, mutect2, varscan2
- HMGB1P1 | n.66T>A | RNA (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
